Surgical pathology report (de-identified scan), TCGA case TCGA-55-7994, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7994-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

PROCEDURE DATE: [REDACTED] RECEIVED DATE: [REDACTED] REPORT DATE: [REDACTED]

COPY TO: [REDACTED]

IO Consultation

FS DIAGNOSIS: "No neoplasm (reported to [REDACTED] positive patient ID)" by [REDACTED] campus [REDACTED]

Pre-Op Diagnosis

Right lung mass

Post-Op Diagnosis

Same as above

Clinical History

Nothing indicated

Gross Description:

Four parts

Container labeled [REDACTED] lymph node" has 1.6 x 1.0 x 0.5 cm of gray-tan to brown tissue fragments with multiple staples. The tissue away from the staples is submitted in a single cassette.

Container labeled [REDACTED] lymph node" has 2.0 x 1.6 x 0.9 cm of lobulated to shaggy tan-gray to yellow fibroadipose tissue fragments which are entirely submitted in a single cassette.

Container labeled [REDACTED] - right upper lobe lung" has a 231 gram previously partially sectioned portion of recognizable pulmonary parenchyma received after tissue harvest for genomic study. The specimen appears grossly consistent with right upper lobe of lung measuring on reconstruction 18.2 x 13.4 x 5.7 cm. The margin of resection is the bifurcation of the tertiary bronchi. Adjacent to the bronchial margin is 1.6 cm gray-black fleshy nodule with a fleshy gray-black cut surface. The pleura is wrinkled mottled gray-tan to pink with moderate anthracotic streaking. Noted on the posterior aspect at a point 3.5 cm from the apex there is a 4.6 x 3.5 cm area of indurated pleural umbilication. The specimen is sectioned within this region to reveal a well defined 7.8 x 6.2 x

[REDACTED]

[page 2 of 3]
4.6 cm lobulated tan-gray gritty fibrotic nodule with a gritty gray-tan necrotic fibrotic cut surface. This is seen at its nearest point 3.5 cm from the nearest bronchial margin. An apparent bronchial connection is identified. The bronchial margin is shaved and submitted for frozen section which is reported as "no neoplasm (reported to [REDACTED] positive patient ID)" by [REDACTED]. On sectioning, the lesion grossly extends to but not through the pleura on the posterior aspect. On sectioning, the remaining parenchyma reveals crepitant gray-tan to pink moderately anthracotic streaked parenchyma without additional gross lesions. Noted on the lateral pleura is a 0.5 x 0.4 x 0.1 cm deep brown to black plaque. Also received in the same container are three tissue cassettes each labeled [REDACTED]. Representative sections are submitted labeled as follows: A - frozen section residue; B - peribronchial nodule bisected; C-G - lesion and surrounding tissue; H - pleural with lateral plaque; I - remaining uninvolved parenchyma.

Container labeled [REDACTED] lymph node" has a 2.4 x 1.7 x 0.6 cm irregular portion of gray-tan to yellow fibroadipose-appearing tissue which is bisected and entirely submitted in a single cassette.

Microscopic Description:

Sections of the first specimen identified as a level 10 lymph node and further identified as specimen #1 from the patient [REDACTED] are examined. These show portions of lymph node and fibrous tissue. The lymph node shows focal germinal center formation. There are histiocytes present within the sinusoids focally. Immunohistochemical stains are performed to verify that these are histiocytes. The cells in question are positive for CD68 and negative for AE1/AE3. The control slides stain appropriately. Additionally, special stains for acid fast bacilli and fungi are performed on this material. No organisms are seen in these preparations. The control slides stain appropriately.

Sections of the second specimen identified as level 7 lymph node show fragments of lymph node and fibroadipose tissue. The lymph node tissue shows germinal center formation. No areas of metastatic carcinoma are seen.

Sections of the third specimen from the right upper lobe of the lung show the bronchial margin to be histologically unremarkable. Sections of a peribronchial lymph node show portions of a lymph node with small germinal center formation and numerous pigment containing histiocytes. No areas of metastatic carcinoma are seen. An additional peribronchial lymph node is seen in one of the tissue sections of the lung. No areas of carcinoma are seen in this lymph node as well. The large neoplasm is composed of sheets of cells that have abundant slightly granular cytoplasm and enlarged, markedly pleomorphic irregular nuclei with prominent nucleoli. Focal areas of necrosis are seen. The neoplasm extends to the pleura in one area. The pleura has been marked with India ink and in this one particular area, the neoplasm is covered by ink. There is no extension beyond the pleura seen in this area. Sections of uninvolved lung show dilated air spaces from broken alveolar walls. The broken alveolar walls show some fibrous clubbing.

Sections of the four specimen identified as the level 4 right lymph node show portions of an unremarkable lymph node with no areas of

[REDACTED]

[page 3 of 3]
metastatic carcinoma.

Final Diagnosis

Lymph node, level 10, excision:

No metastatic carcinoma present.

Reactive hyperplasia with chronic inflammation.

No organisms seen on special stains, diagnosis confirmed by immunohistochemical stains.

Lymph node, level 7, excision:

No metastatic carcinoma present.

Mild reactive hyperplasia.

Lymph node, level 4 right, excision:

No metastatic carcinoma present.

Mild reactive hyperplasia.

Lung, right upper lobe, lobectomy:

Tumor characteristics:

Histologic type: Poorly differentiated adenocarcinoma.

Grade: 3

Tumor site: Right upper lobe.

Specimen integrity: Specimen intact.

Tumor focality: Unifocal.

Tumor size: 7.8 x 6.2 x 4.6 cm.

Visceral pleural invasion: Present, no extension beyond pleura identified histologically.

Lymphovascular space invasion: No.

Treatment effect: Not applicable.

Surgical margin status:

Tumor distance from closest bronchial margin: 3.5 cm.

Tumor distance from pleural space: Neoplasm involves visceral peritoneum.

Lymph node status:

Total number of lymph nodes received: 5 (three as stated above and two peribronchial lymph nodes within the specimen).

Total number of lymph nodes containing metastatic carcinoma: 0

Other:

Moderate pulmonary emphysema.

Diagnosis of adenocarcinoma confirmed by immunohistochemical stains. PAS 9

Stage: pT3N0

CPT: 88331, 88305 x3, 88309, 88342 x6, 88313 x2 [REDACTED]

Comments

The permanent section diagnosis confirms the frozen section diagnosis.

This report has been finalized at the [REDACTED]

This test was developed and its performance characteristics determined by [REDACTED] Laboratory. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

Source: NCI Genomic Data Commons file ce5b895e-bd41-46dc-8cef-00e0aaaabc03 (TCGA-55-7994.8454B0FE-A466-43B7-843F-16DB8B4C43CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).